TCGA case TCGA-BP-4354 — Kidney Renal Clear Cell Carcinoma (TCGA-KIRC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: MSKCC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d9208e7b-0b47-43ff-a4e8-d4e591e286c4

Demographics
Sex at birth: male; Race: white; Age at index: 40 years; Vital status: Dead; Days to death: 1,034 days (2.8 years).

Diagnoses (2)
1. Clear cell adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8310/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 41.0 years (14,973 days); Year of diagnosis: 2006; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 21.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Gefitinib; Treatment intent type: Neoadjuvant; Days to treatment start: 10 days; Days to treatment end: 454 days (1.2 years); Number of cycles: 11; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Treatment intent type: Neoadjuvant; Days to treatment start: 10 days; Days to treatment end: 454 days (1.2 years); Number of cycles: 11; Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sunitinib; Treatment intent type: Adjuvant; Days to treatment start: 490 days (1.3 years); Days to treatment end: 525 days (1.4 years); Number of cycles: 3; Prescribed dose: 25; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Initial disease status: Progressive Disease; Days to treatment start: 583 days (1.6 years); Days to treatment end: 589 days (1.6 years); Number of cycles: 1; Prescribed dose: 400; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Sorafenib; Treatment intent type: Adjuvant; Days to treatment start: 595 days (1.6 years); Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Palliative; Days to treatment start: 685 days (1.9 years); Days to treatment end: 701 days (1.9 years); Treatment dose: 4,000 cGy; Course number: 1; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Palliative; Days to treatment start: 702 days (1.9 years); Days to treatment end: 702 days (1.9 years); Treatment dose: 1,800 cGy; Course number: 2; Number of fractions: 1; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Temsirolimus; Days to treatment start: 721 days (2.0 years); Treatment outcome: Treatment Ongoing; Route of administration: Intravenous.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 42.9 years (15,658 days); Days to diagnosis: 685 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS to Distant Site; Surgery, NOS to Locoregional Site.

Follow-up (2 entries)
- Day 685 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 1,034 days (2.8 years); Disease response: With Tumor.

Molecular and laboratory tests
- Platelets: Normal.
- Hemoglobin: Low.
- Leukocytes: Normal.
- Lactate Dehydrogenase: Normal.
- Calcium: Normal.

Exposures
- Exposure type: Tobacco.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BP-4354-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.3; Intermediate dimension: 1.4; Shortest dimension: 0.4.
  Slide TCGA-BP-4354-01A-01-BS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 15.
  Slide TCGA-BP-4354-01A-02-BS2: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 20.
- Sample TCGA-BP-4354-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BP-4354-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.3.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Clear Cell Renal Carcinoma; History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Hemoglobin level: Low; Lymph nodes examined: Yes.
- Drug treatment 1: Regimen number: 5; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Patient cannot tolerate sorafenib.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Therapy regimen: OTHER, SPECIFY IN NOTES.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 3: Regimen number: 4.
- Drug treatment 4: Regimen number: 2.
- Drug treatment 5: Regimen number: 3; Therapy regimen: Progression.
- Radiation treatment 1: Radiation type other: Stereotactic Radiosurgery.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No.
- Follow-up form 2: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Neoadjuvant therapy: Subject Positive for Neo-Adjuvant Therapy.
- Neoadjuvant therapy: Patient received neo-adjuvant gefinitib and sunitinib for tumor submitted to TCGA.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,034 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,034 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 685 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-BP-4354-01): tumor purity 0.21, ploidy 1.96, whole-genome doublings 0 (call status: legacy_call).
